Somatic mutation profile of tumor specimen TCGA-EJ-7781-01A (aliquot TCGA-EJ-7781-01A-11D-2114-08) from TCGA case TCGA-EJ-7781, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.5 years (23,937 days).
Specimen TCGA-EJ-7781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a60d2833-4a5f-4800-a6e3-7825865b9e24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7781-10A (Blood Derived Normal), aliquot TCGA-EJ-7781-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4411a9f-4422-4012-8872-bb5eed344ec8

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1890T>A p.D630E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.1); catalogued as COSV53900492; called by muse, mutect2, varscan2
- ANKRD45 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs753085501, COSV100322588, COSV60960416; called by muse, mutect2, varscan2
- DAPK1 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV63785450; called by muse, mutect2, varscan2
- DIP2C | c.4496T>C p.V1499A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV55150426; called by muse, mutect2, varscan2
- ERLIN2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV52419787; called by muse, mutect2
- ERLIN2 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52419822; called by muse, mutect2
- EXOC1 | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV62119489; called by muse, mutect2, varscan2
- FAM83B | c.1642C>A p.P548T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV60920273, COSV60926609; called by muse, mutect2
- FBXO38 | c.1531A>C p.N511H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV57026467; called by muse, mutect2, varscan2
- FLG2 | c.1032C>G p.N344K | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV66167278; called by muse, mutect2
- GABRD | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV66080052; called by muse, mutect2
- GABRE | c.825G>C p.R275S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64819164; called by muse, mutect2, varscan2
- HPCA | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV65102828; called by muse, mutect2, varscan2
- IQGAP1 | c.4858C>T p.Q1620* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as rs755073388, COSV51582700; called by muse, mutect2
- KANK2 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62007122; called by muse, mutect2, varscan2
- KLHL7 | c.1379C>G p.T460R (on ENST00000339077 / NM_001031710.3; = p.T412R on NM_018846.5) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59160357; called by muse, mutect2
- MGAT5B | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV56926798; called by muse, mutect2
- NHS | c.4411A>G p.T1471A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs754367608, COSV66272691; called by muse, mutect2, varscan2
- OR5AS1 | c.655T>A p.F219I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.059); catalogued as COSV57981171; called by muse, mutect2
- PCDHA7 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs782068965, COSV65342768; called by muse, mutect2
- PCDHGA2 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); catalogued as rs1475554511, COSV53899507; called by muse, mutect2
- PCSK2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs1184065413, COSV52728294; called by muse, mutect2
- PKHD1 | c.9459T>G p.F3153L | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as COSV61865706; called by muse, mutect2
- PLAU | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV65641036; called by muse, mutect2
- PRAMEF2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs143742734; called by muse, mutect2, varscan2
- RBP3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs368898051; ClinVar: uncertain significance; called by muse, mutect2
- RNF103 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763929414, COSV52894075; called by muse, mutect2, varscan2
- RNF31 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53758777; called by muse, mutect2
- SAP130 | c.2804A>G p.N935S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV52095292; called by muse, mutect2
- SCN1A | c.4100A>G p.N1367S (on ENST00000303395 / NM_001202435.3; = p.N1356S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57663964; called by muse, mutect2
- SCN1A | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs750516202, CM152271, COSV57663983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STARD8 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1457248199, COSV52923219; called by muse, mutect2, varscan2
- TP53 | c.956del p.K319Rfs*26 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as COSV53486415; called by mutect2, pindel, varscan2
- TTN | c.11245G>C p.D3749H (on ENST00000591111; = p.D3703H on NM_003319.4) | Missense Mutation (SNP) | VAF 53/198 reads (27%) | catalogued as COSV59940640; called by muse, mutect2, varscan2
- ZC3H7B | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV60960963; called by muse, mutect2, varscan2
- ZEB1 | c.1777T>A p.L593M | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.173); catalogued as COSV58039329; called by muse, mutect2
- ZNF443 | c.1631A>T p.Y544F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56890781; called by muse, mutect2, varscan2
- BRCC3 | c.239del p.L80Yfs*11 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- IGHV3-11 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UBXN4 | c.1075_1077del p.N359del | In Frame Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel, varscan2
- AXIN2 | c.765G>C p.L255= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV61056335; called by muse, mutect2
- CAMSAP3 | c.3255T>C p.P1085= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV50331728; called by muse, mutect2
- CFAP46 | c.8007G>C p.L2669= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1228680674, COSV54150243; called by muse, mutect2, varscan2
- FAM111A | c.540A>G p.E180= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV64655144; called by muse, mutect2, varscan2
- GLB1L3 | c.1242G>A p.P414= | Silent (SNP) | VAF 30/460 reads (7%) | catalogued as rs1236064997, COSV68392493; called by muse, mutect2
- HBE1 | c.348T>A p.A116= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as COSV53079708; called by muse, mutect2, varscan2
- PCDHA5 | c.1404G>A p.P468= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as rs17844294, COSV65350487; called by muse, varscan2
- RHOJ | c.129C>T p.N43= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1207287812, COSV57457287; called by muse, mutect2, varscan2
- SLC4A11 | c.426C>T p.N142= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs750376981, COSV66260908; called by muse, mutect2, varscan2
- SPTB | c.4392G>A p.L1464= | Silent (SNP) | VAF 6/151 reads (4%) | catalogued as COSV67630448; called by muse, mutect2
- STAB2 | c.4512C>T p.Y1504= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as COSV66336148; called by muse, mutect2
- THSD7B | c.549T>G p.S183= | Silent (SNP) | VAF 18/313 reads (6%) | catalogued as COSV55664696; called by muse, mutect2
- TRIM21 | c.333C>T p.C111= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV54343109; called by muse, mutect2
- OR5AU1 | c.-117A>G | 5'UTR (SNP) | VAF 12/177 reads (7%) | catalogued as rs1189691295, COSV58615368; called by muse, mutect2
